Surgical pathology report (de-identified scan), TCGA case TCGA-33-4566, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-4566-01A (Primary Tumor).

AL DIAGNOSIS ----- Pathologist: [REDACTED]

1. BRONCHUS (MARGIN BX): BRONCHIAL MUCOSA, NEGATIVE FOR TUMOR.
2. LYMPH NODE, R10 (EXCISION): ONE (1) LYMPH NODE, NEGATIVE FOR TUMOR.
3. LYMPH NODE, R11 (EXCISION): TWO (2) LYMPH NODES, NEGATIVE FOR TUMOR.
4. LUNG, RIGHT UPPER LOBE (LOBECTOMY):
- INFILTRATING POORLY DIFFERENTIATED NON-SMALL CELL CARCINOMA (LARGE CELL UNDIFFERENTIATED CARCINOMA) WITH FOCAL SQUAMOUS FEATURES OF THE LUNG. THE CARCINOMA MEASURES 5.6 CM IN GREATEST DIMENSION. IT OBLITERATES A LARGE BRONCHUS FROM WHICH IT MAY HAVE ARISEN IN THE APICAL MEDIAL SEGMENT OF THE RIGHT UPPER LOBE. THE CARCINOMA DOES NOT INVOLVE THE PLEURAL SURFACE. THE BRONCHIAL, VASCULAR, AND PARENCHYMAL MARGINS AND EIGHT (8) REGIONAL LYMPH NODES ARE NEGATIVE FOR TUMOR.
- THE NON-NEOPLASTIC LUNG ADJACENT TO THE TUMOR SHOWS NUMEROUS
- [REDACTED]
- [REDACTED]

Source: NCI Genomic Data Commons file 2d19692e-a6e7-40fc-82d1-1612e00ffce8 (TCGA-33-4566.CD1A9BA4-3CCF-4F10-B512-A76BAA9D8D44.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).